Surgical pathology report (de-identified scan), TCGA case TCGA-09-1673, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-1673-01A (Primary Tumor).

[page 1 of 3]
FINAL PATHOLOGIC DIAGNOSIS

- A. Omentum, omentectomy: Metastatic high-grade serous carcinoma.
B. Ovary and fallopian tube, left, excision: Ovary and fallopian tube completely replaced by high-grade serous carcinoma; see comment.
C. Ovary and fallopian tube, right, excision:
1. Ovary and fallopian tube with high-grade serous carcinoma; see comment.
2. Leiomyoma in soft tissue adjacent to ovary, uninvolved by ovarian tumor.
D. Mesentery, mass, biopsy: Metastatic high-grade serous carcinoma.
E. Residual omentum, excision: Metastatic high-grade serous carcinoma.
F. Skin, subcutaneous nodule, excision: Skin and subcutaneous tissue with metastatic high-grade serous carcinoma, extends to margin of resection.

COMMENT:

Focal areas with clear cell changes and sarcomatoid cell morphology are noted, which can be seen in this type of tumor. The percentage of these areas is <5% of the total tumor.

Ovarian Tumor Synoptic Comment

- **Location of tumor:** Bilateral.
- **Type of tumor:** Serous.
- **Grade of tumor:** 3.
- **Size of tumor:** Left ovary and fallopian tube: 10 cm.
Right ovary and fallopian tube: 8.5 cm.
- **Surface of ovary:** Tumor on surface.
- **Condition of capsule:** Ruptured.
- **Cut surface:** Solid (minor cystic areas).
- **Necrosis:** Focal.
- **Lymphatic/vascular invasion:** Present (best seen in slide B2).
- **Sites of metastases in pelvis:** Fallopian tube, other (omentum and mesentery).
- **Size of largest pelvic metastasis is entire omentum:** >2 cm (see gross description).
- **Pelvic lymph nodes:** None present.
- **Sites of metastases in abdomen:** Omentum and serosa of bowel.
- **Size of largest abdominal metastasis is entire omentum:** >2cm (see gross description).
- **Para-aortic lymph nodes:** None sampled.
- **Peritoneal cytology:** Positive. (Cytology accession number: [REDACTED])
- **Other findings:** None.
- **FIGO stage:** 4.
- **AJCC stage:** pT3cNXM1.

[REDACTED] has reviewed the case and agrees with the above diagnoses.

Specimen(s) Received

A: Omentum (Oncotech)

[page 2 of 3]
[REDACTED]

B:Left tube and ovary (fresh)
C:Right tube and ovary (fresh)
D:Mesenteric mass
E:Residual omentum
F:Subcutaneous nodule

Clinical History

The patient is a [REDACTED] with advanced stage ovarian cancer. She now undergoes exploratory laparotomy, bilateral salpingo-oophorectomy, omentectomy and tumor reductive surgery.

Gross Description

The specimen is received in six parts, each labeled with the patient's name and medical record number. Parts A-C are received fresh. Parts D-F are received in formalin. Part A is received fresh and additionally labeled "omentum." It consists of one firm, pink-white/yellow-brown, irregular, unoriented, multinodular tissue fragment that measures 37 x 21.5 x 6 cm and weighing 1368 grams. The specimen is approximately 100% nodular. A representative section is submitted to Oncotech. A representative section is submitted for ovarian tissue banking. Representative sections are submitted in cassettes A1-A4. Part A has been grossly reviewed by [REDACTED]. The remaining tissue is returned to the container. [REDACTED]

Part B is additionally labeled "left tube and ovary," and consists of a morcellated yellow-tan, irregular soft tissue specimen measuring 10 x 8.5 x 2.5 cm in aggregate and weighing 86 grams in toto. There are several dilated cysts or ducts filled with yellow-tan, mucoid substance, the largest measuring 1.1 cm in greatest diameter. In addition, there is a white, firm tissue fragment with ill-defined borders measuring 2.5 x 1.2 x 1 cm. The remaining parts of the specimen are tan, rough and studded with numerous white nodules up to 1 cm. Tissue samples are taken for ovarian tumor banking, and photos are taken. Representative sections are submitted in cassettes B1-B5. [REDACTED]

Part C is additionally labeled "right tube and ovary," and consists of a single irregular adnexa resection. The specimen is received measuring 8.5 x 5.5 x 3 cm and weighing 58 grams. There is a disrupted candidate fallopian tube and ovary present that is partially encased in white-tan-yellow irregular mass. The candidate ovary measures 2.2 x 1.5 x 1.5 cm, with a white-tan, whorled interior. The candidate fallopian tube measures 0.5 cm in average diameter. The surrounding mass is white-tan-yellow and firm. Sections are submitted as follows:

Cassette C1: Candidate ovary and adjacent soft tissue.

[page 3 of 3]
[REDACTED]

Cassette C2: Candidate fallopian tube and mass.
Page 2 of 3

[REDACTED]

Cassettes C3-C5: Mass, representative. [REDACTED]

Part D, additionally labeled "mesenteric mass," consists of multiple white-tan/brown, irregular, unoriented, firm tissue fragments that are 7 x 4.5 x 1.5 cm and 21.6 grams in aggregate.

Representative sections are submitted in cassettes D1-D3 at a rate of one section per centimeter.

The remaining tissue is returned to the container. This specimen was grossly reviewed by [REDACTED]

Part E, additionally labeled "5 - residual omentum," consists of one white-yellow, irregular, unoriented, firm tissue fragment that is 95% nodular. It is 5.6 x 3.1 x 2 cm.

Representative sections are submitted in cassettes E1-E3. The remaining tissue is returned to the container. [REDACTED]

Part F, additionally labeled "6 - subcutaneous nodule," consists of one pink-tan, irregular, unoriented, elliptical skin fragment with a central defect. The specimen is 4 x 1 x 2.5 cm. The defect is 0.6 x 0.1

cm. The defect is 1.4 cm from a tip, 2 cm from the opposite tip, 0.5 cm from the side, and 0.3 cm

from the opposite side. The resection margin is inked blue. The specimen is serially sectioned

parallel to the long axis revealing yellow subcutaneous tissue, with white, diffuse, firm tissue

subjacent to the skin. The firm area abuts the resection margin. Representative sections are

submitted in cassettes F1-F3 as follows:

Cassette F1: Tips.

Cassettes F2-F3: Full-thickness central defect showing area of white, diffuse tissue.

The remaining tissue is returned to the container. Part F has been reviewed by Dr. [REDACTED]

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending

pathologist following review of all pathology slides.

[REDACTED]

Source: NCI Genomic Data Commons file 1410986d-bed0-4ea9-b15a-6cf7c2e556b8 (TCGA-09-1673.D4F7AA96-11E8-4D66-A1BE-595EC22DE450.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).